FM case AD16442 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms; Primary site: Vulva.
https://portal.gdc.cancer.gov/cases/0e4e0906-4d15-4b71-b4e6-92b7e5cf8f8e

Female, 78.5 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3) of the vulva; primary biopsied or resected from the vulva. Tumor nuclei on the sequenced sample's slide: 30% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
